Gene-level copy-number profile of tumor specimen TCGA-2G-AAHY-01A from TCGA case TCGA-2G-AAHY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.6 years (19,225 days).
Specimen TCGA-2G-AAHY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62bd59e3-92be-4399-a18f-5f31d6ebaef5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/9db9d691-23b4-45d8-9374-a0ad63b341ae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,022; copy number 2: 16,973; copy number 3: 28,684; copy number 4: 9,769; copy number 5: 2,312; copy number 6: 57; copy number 7: 2; copy number 8: 80; copy number 14: 6.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,981,436–8,990,806, 2 genes: AC073648.3, AC073648.2.
- chr18:45,034–94,330, 5 genes: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 88 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,355,778–41,157,555, 80 genes, copy number 8 (broad region; genes not listed).
- chr22:18,361,820–18,524,935, 8 genes, copy number 7–14: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
